Somatic mutation profile of tumor specimen TARGET-10-PANXLP-09A (aliquot TARGET-10-PANXLP-09A-01D) from TARGET case TARGET-10-PANXLP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,199 days).
Specimen TARGET-10-PANXLP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b30ba6a7-084d-4c79-8ed2-40468d9f8a42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANXLP-10A (Blood Derived Normal), aliquot TARGET-10-PANXLP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52129bd4-7107-46fd-9dc3-a606dcc7fe09

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRRIQ1 | c.3420T>A p.N1140K | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV67840603; called by muse, mutect2
- OR52A1 | c.894G>C p.K298N | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100200511; called by muse, mutect2, varscan2
- GATA6 | c.77C>A p.A26D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ITGB1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CTBP1 | c.1254C>T p.P418= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- MYO18B | c.7398C>T p.D2466= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as rs767843589; ClinVar: likely benign; called by muse, mutect2
- RSPO4 | c.135C>T p.N45= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs1235248369, COSV54080151, COSV99449160; called by muse, mutect2, varscan2
- SPTB | c.6918C>T p.S2306= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs750587649; called by muse, varscan2
- TTLL7 | c.1027C>T p.L343= | Silent (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- SRPK1 | c.1691-43G>A | Intron (SNP) | VAF 21/76 reads (28%) | catalogued as rs771236043, COSV60414028; called by muse, mutect2, varscan2
